TCGA case TCGA-D7-A4Z0 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Stomach; Tissue source site: Greater Poland Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dce21359-004f-4e8b-89e4-9e1a30faffdf

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Poland; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; ICD-10 code: C16.3; Tissue or organ of origin: Gastric antrum; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 60.6 years (22,129 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 449 days (1.2 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 10.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 72 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 100 days; Days to treatment end: 136 days; Treatment dose: 45 Gy; Treatment outcome: Stable Disease; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.

Follow-up (2 entries)
- Days to follow up: 148 days; Disease response: Tumor Free.
- Days to follow up: 449 days (1.2 years); Disease response: Tumor Free.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D7-A4Z0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 130 mg.
  Slide TCGA-D7-A4Z0-01A-02-TS2: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 6; Percent stromal cells: 69; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-D7-A4Z0-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D7-A4Z0-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Mucinous Type; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Antrum/Distal; Lymph nodes examined: Yes; Cancer procurement city: Poznan; Antireflux treatment: No; History barretts esophageal indicator: No; History hpylori infection indicator: No; New tumor event diagnosis indicator: No.
- Drug treatment: Pharmaceutical therapy drug name: 5-fluorouracilum.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 449 days; disease-specific survival: no event (censored), 449 days; disease-free interval: no event (censored), 449 days; progression-free interval: no event (censored), 449 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D7-A4Z0-01A-22D-A253-01): tumor purity 0.31, ploidy 2.2, whole-genome doublings 0.
